Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABK9, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABK9-TTP2-A (Primary Tumor).

Material description

- A) Lower Lobe, right lung
- B) Medium pulmonary lobe, lung
- C) Hilar lymph nodes
- D) Subcarinal lymph nodes
- E) Paraesophageal lymph nodes

ICB-0-3
adenocarcinoma with mixed subtypes 8255/3
Site: (R) lung, lower lobe C34.3

ICB-10

C34.31

hw
2/12/16

Macro description

A) Pulmonary lobe 12 x 11 x 4.5 cm showing, when you cut, white-brownish neoformation, solid - elastic compactness, centrally cavitated, bigger axis 3,5 cm, that ulcerates the above visceral pleura and is far 4,5 cm from margin of resection of the same. We do intraoperative examination. The remaining parenchyma is partly congested and partly emphysematous. We close off 8 peribronchial lymph nodes (A1 definitive at freezer; A2 -A4 neoplasm; A5 parenchyma at distance, Ab margin of vascular and bronchial resection, A7-A9 peribronchial lymph nodes).

A) 8.5 x 7.5 x 3 cm pulmonary lobe closed by metal stitches for a length of 8 cm, markedly congested when you cut. We close off one peribronchial lymph node.

(B1 margin of bronchial resection, and one peribronchial lymph node, B2 parenchyma).

B) 3 lymph nodes of bigger axis between 0.3 cm and 0.5 cm.

C) One lymph node of bigger axis of 1.5 cm

D) 2 lymph nodes of bigger axis of 1.2 cm and 1.5 cm.

CDDP-YP-ABK9-01-PR

**Micro description**

A,C,D, Pulmonary mixed adenocarcinoma, acinar moderately differentiated and bronchiolo-alveolar with mucinous aspects (WHO 1999), infiltrating the visceral pleura and extended to 4/8 pulmonary isolated lymph nodes and to lymph nodes of samples D and E.

Subatelectasis in the remaining pulmonary parenchyma.

Histiocytosis and black lung disease of sinuses in the remaining peribronchial isolated lymph nodes and in that of the sample C.

Intraoperative diagnosis of A : no small cells carcinoma

B) Pulmonary subatelectactic parenchyma, free of neoplasm

Margin of bronchial resection without histological important alterations.

Histiocytosis and black lung disease of sinuses in the peribronchial isolated lymph node.

Staging pTNM: pT2. N2

Source: NCI Genomic Data Commons file ae766fdc-748c-4e7f-82d7-1f5fdf88168a (CDDP-ABK9-TTP2.15B77650-6C05-40AE-A959-6058CF1C5DBE.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).